Somatic mutation profile of tumor specimen TCGA-L5-A88Z-01A (aliquot TCGA-L5-A88Z-01A-11D-A36J-09) from TCGA case TCGA-L5-A88Z, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle third of esophagus; AJCC pathologic stage: Stage IIA; Tumor grade: GX; Age at diagnosis: 70.9 years (25,890 days).
Specimen TCGA-L5-A88Z-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1a8292bb-a26f-4c74-a6a2-8b2b3ffacb15.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-L5-A88Z-11A (Solid Tissue Normal), aliquot TCGA-L5-A88Z-11A-11D-A36M-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7e1edce1-31fa-4158-bf7d-b4dfb8afb304

The open-access MAF lists 76 somatic variants for this specimen: 58 protein-altering or splice-affecting, 18 silent.
By variant classification: Missense Mutation 43, Silent 18, Nonsense Mutation 7, Splice Site 3, Frame Shift Ins 3, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1513C>G p.R505G (on ENST00000281708 / NM_001349798.2; = p.R425G on NM_018315.5) | Missense Mutation (SNP) | VAF 30/58 reads (52%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149680468, COSV55890969, COSV55891274, COSV55898451; ClinVar: likely pathogenic; called by muse, varscan2
- NFE2L2 | c.70T>A p.W24R | Missense Mutation (SNP) | VAF 13/24 reads (54%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67960091, COSV67960815, COSV67963035; called by muse, mutect2, varscan2
- TP53 | c.523C>G p.R175G | Missense Mutation (SNP) | VAF 14/40 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs138729528, CM011013, CM118880, COSV52688031, COSV52713177, COSV52717943, COSV53372849; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- TP53 | c.328C>T p.R110C | Missense Mutation (SNP) | VAF 86/161 reads (53%) | hotspot (GDC flag); SIFT tolerated (0.14); PolyPhen benign (0.047); catalogued as rs587781371, CD136796, COSV52684761, COSV53551526; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALDOC | c.77C>T p.P26L | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.122); catalogued as rs752045255, COSV52024147; called by muse, mutect2, varscan2
- ARID1A | c.6527del p.Q2176Rfs*24 | Frame Shift Del (DEL) | VAF 17/36 reads (47%) | catalogued as COSV61386852; called by mutect2, pindel, varscan2
- CRTAM | c.283G>A p.V95M | Missense Mutation (SNP) | VAF 45/105 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.13); catalogued as rs757374307; called by muse, mutect2, varscan2
- DCTN1 | c.991C>T p.R331W | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.545); catalogued as rs1064797256; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EPHB4 | c.1555G>A p.G519S | Missense Mutation (SNP) | VAF 14/196 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.195); catalogued as rs761047725; called by muse, mutect2
- EXT1 | c.2221C>T p.R741* | Nonsense Mutation (SNP) | VAF 20/55 reads (36%) | catalogued as COSV65484530; called by muse, mutect2, varscan2
- FBN2 | c.7288A>G p.T2430A | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs1014393573; called by muse, mutect2, varscan2
- GCG | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs757350391, COSV64961135; called by muse, mutect2, varscan2
- KEAP1 | c.1238G>A p.R413H | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50260479, COSV50262144; called by muse, mutect2, varscan2
- KIAA1109 | c.1288G>A p.G430S | Missense Mutation (SNP) | VAF 94/250 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs775448550; called by muse, mutect2, varscan2
- MIA2 | c.622C>G p.R208G | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.017); catalogued as COSV54484273; called by muse, mutect2, varscan2
- MIIP | c.170C>T p.T57M | Missense Mutation (SNP) | VAF 36/50 reads (72%) | SIFT tolerated (0.23); PolyPhen benign (0.035); catalogued as rs200638129; called by muse, mutect2, varscan2
- MMP3 | c.569G>T p.G190V | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV55406673; called by muse, mutect2, varscan2
- MYL10 | c.631G>C p.D211H | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV56207736, COSV56208396, COSV56209232; called by muse, mutect2
- NCAM2 | c.619G>A p.V207M | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV99525521; called by muse, mutect2
- OBSCN | c.12368C>T p.T4123M | Missense Mutation (SNP) | VAF 41/74 reads (55%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as rs765062164, COSV52839665; called by muse, mutect2, varscan2
- OR4L1 | c.547dup p.L183Pfs*9 | Frame Shift Ins (INS) | VAF 16/52 reads (31%) | catalogued as rs35605617; called by mutect2, pindel, varscan2
- PAPPA2 | c.1912G>A p.D638N | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0.044); catalogued as rs1168232006, COSV62772967; called by muse, mutect2, varscan2
- PSTPIP1 | c.184C>T p.R62W | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs375063664; called by muse, mutect2, varscan2
- RFPL3 | c.442C>T p.R148* (on ENST00000249007 / NM_001098535.1; = p.R119* on NM_006604.2) | Nonsense Mutation (SNP) | VAF 49/109 reads (45%) | catalogued as rs374358387; called by muse, mutect2, varscan2
- ROS1 | c.2469G>T p.Q823H | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.98); catalogued as COSV104423666; called by muse, mutect2, varscan2
- SALL3 | c.1915G>A p.V639I | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs557725030; called by muse, mutect2, varscan2
- SEPTIN4 | c.1135C>A p.P379T | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as COSV58727037, COSV58727048; called by muse, mutect2, varscan2
- SEPTIN8 | c.1201C>T p.R401W | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs374687255; called by muse, mutect2, varscan2
- TMEM190 | c.398G>A p.R133Q | Missense Mutation (SNP) | VAF 45/105 reads (43%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.141); catalogued as rs1464412728, COSV52581817; called by muse, mutect2, varscan2
- WASL | c.58C>G p.L20V | Missense Mutation (SNP) | VAF 22/206 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as COSV56133904; called by muse, mutect2, varscan2
- CDH12 | c.1255A>G p.R419G | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- CNNM2 | c.1723G>T p.E575* | Nonsense Mutation (SNP) | VAF 30/86 reads (35%) | called by muse, mutect2, varscan2
- COL25A1 | c.514C>A p.H172N | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- COL9A1 | c.1504-1G>C p.X502_splice | Splice Site (SNP) | VAF 14/42 reads (33%) | called by muse, mutect2, varscan2
- COMTD1 | c.607C>T p.R203* | Nonsense Mutation (SNP) | VAF 24/63 reads (38%) | called by muse, mutect2, varscan2
- ERCC6 | c.1923C>A p.H641Q | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- FBXW7 | c.1624_1627dup p.R543Kfs*2 (on ENST00000281708 / NM_001349798.2; = p.R463Kfs*2 on NM_018315.5) | Nonsense Mutation (INS) | VAF 20/79 reads (25%) | called by pindel, varscan2
- FMN2 | c.2597C>T p.S866F | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GBP7 | c.1599G>C p.K533N | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, varscan2
- IFRD2 | c.739-2_739-1del p.X247_splice | Splice Site (DEL) | VAF 15/29 reads (52%) | called by mutect2, pindel, varscan2
- ITPR1 | c.1276G>C p.D426H (on ENST00000354582; = p.D411H on NM_002222.7) | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MUC5B | c.3553C>A p.H1185N | Missense Mutation (SNP) | VAF 41/127 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NIPA1 | c.513dup p.L172Afs*48 | Frame Shift Ins (INS) | VAF 16/39 reads (41%) | called by mutect2, pindel, varscan2
- NLRC5 | c.4488dup p.K1497Efs*35 | Frame Shift Ins (INS) | VAF 17/53 reads (32%) | called by mutect2, pindel, varscan2
- NLRC5 | c.5177A>G p.N1726S | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- NVL | c.538A>T p.S180C | Missense Mutation (SNP) | VAF 40/162 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- PITPNB | c.233A>T p.E78V | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.367); called by muse, mutect2
- PLPBP | c.616G>T p.E206* | Nonsense Mutation (SNP) | VAF 18/51 reads (35%) | called by muse, mutect2, varscan2
- PTK2B | c.1744G>T p.A582S | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.311); called by muse, mutect2, varscan2
- PTPRJ | c.115+2_115+3del p.X39_splice | Splice Site (DEL) | VAF 11/31 reads (35%) | called by mutect2, pindel, varscan2
- PYGB | c.817G>A p.A273T | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- SLC24A5 | c.467C>T p.A156V | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT tolerated (0.99); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SMC2 | c.874A>C p.T292P | Missense Mutation (SNP) | VAF 47/106 reads (44%) | SIFT tolerated (0.35); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- STAG1 | c.1870G>T p.V624L | Missense Mutation (SNP) | VAF 43/75 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- TEX14 | c.2141C>G p.S714* (on ENST00000240361 / NM_001201457.2; = p.S708* on NM_031272.5) | Nonsense Mutation (SNP) | VAF 7/54 reads (13%) | called by muse, mutect2, varscan2
- TRIM41 | c.1770_1777del p.G591Qfs*61 | Frame Shift Del (DEL) | VAF 11/54 reads (20%) | called by mutect2, pindel, varscan2
- VANGL2 | c.911G>A p.G304D | Missense Mutation (SNP) | VAF 85/140 reads (61%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.798); called by muse, mutect2, varscan2
- ZNF784 | c.421T>A p.L141M | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- AGXT2 | c.1116G>A p.A372= | Silent (SNP) | VAF 25/63 reads (40%) | catalogued as rs1207970057, COSV51485094; called by muse, mutect2, varscan2
- AQR | c.1009C>T p.L337= | Silent (SNP) | VAF 21/55 reads (38%) | catalogued as rs750164753, COSV99333939; called by muse, mutect2, varscan2
- ATP8B3 | c.3321C>T p.P1107= | Silent (SNP) | VAF 25/67 reads (37%) | catalogued as rs772876130; called by muse, mutect2, varscan2
- AWAT1 | c.177A>G p.P59= | Silent (SNP) | VAF 42/61 reads (69%) | called by muse, mutect2, varscan2
- C16orf86 | c.612G>A p.L204= | Silent (SNP) | VAF 42/83 reads (51%) | called by muse, mutect2, varscan2
- CFAP61 | c.1725G>T p.L575= | Silent (SNP) | VAF 29/77 reads (38%) | catalogued as COSV55638522; called by muse, mutect2, varscan2
- CYFIP2 | c.462T>C p.S154= | Silent (SNP) | VAF 8/35 reads (23%) | called by muse, mutect2, varscan2
- DLGAP2 | c.255C>T p.S85= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs759970752, COSV70097024; called by muse, mutect2, varscan2
- DSCAML1 | c.2712C>T p.N904= (on ENST00000321322; = p.N844= on NM_020693.4) | Silent (SNP) | VAF 25/49 reads (51%) | catalogued as rs767055301, COSV58386164; called by muse, mutect2, varscan2
- EML2 | c.915C>T p.D305= | Silent (SNP) | VAF 34/91 reads (37%) | catalogued as rs148351202; called by muse, mutect2, varscan2
- ERLEC1 | c.1173G>A p.K391= | Silent (SNP) | VAF 25/59 reads (42%) | catalogued as COSV51753079; called by muse, mutect2, varscan2
- IQCE | c.1830C>T p.S610= | Silent (SNP) | VAF 65/151 reads (43%) | catalogued as rs764063887, COSV100383811; called by muse, mutect2, varscan2
- KCNQ2 | c.264G>A p.P88= | Silent (SNP) | VAF 20/63 reads (32%) | catalogued as COSV100609674; called by muse, mutect2, varscan2
- OR4A5 | c.222C>T p.T74= | Silent (SNP) | VAF 23/53 reads (43%) | catalogued as COSV60521788; called by muse, mutect2, varscan2
- OR5B2 | c.75C>T p.L25= | Silent (SNP) | VAF 28/78 reads (36%) | called by muse, mutect2, varscan2
- PHOX2A | c.246C>T p.S82= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as COSV53353897; called by muse, mutect2, varscan2
- PLXNA4 | c.1722C>T p.N574= | Silent (SNP) | VAF 41/96 reads (43%) | catalogued as rs759386370, COSV58117902, COSV58155656; called by muse, mutect2, varscan2
- SHCBP1 | c.1614T>C p.N538= | Silent (SNP) | VAF 9/105 reads (9%) | called by muse, mutect2
